Somatic mutation profile of tumor specimen TCGA-24-2038-01A (aliquot TCGA-24-2038-01A-01W-0722-08) from TCGA case TCGA-24-2038, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: GB; Age at diagnosis: 68.3 years (24,957 days).
Specimen TCGA-24-2038-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e49d8ca-5e40-4125-9de4-02f276f6b1ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2038-10A (Blood Derived Normal), aliquot TCGA-24-2038-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b27b839c-5475-4635-a370-3265509d671d

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 52/94 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADPGK | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100295410; called by muse, mutect2
- DNAH10 | c.7043A>G p.Y2348C (on ENST00000409039; = p.Y2287C on NM_207437.3) | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV68990649; called by muse, mutect2, varscan2
- DNMBP | c.4171G>A p.A1391T | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs772574320, COSV60622825; called by muse, mutect2, varscan2
- EMSY | c.2570C>A p.S857Y | Missense Mutation (SNP) | VAF 156/338 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV58258659; called by muse, mutect2, varscan2
- MC2R | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758727564, COSV59617553, COSV59619547; called by muse, mutect2, varscan2
- SSX2IP | c.1022G>A p.S341N | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV60551896; called by muse, mutect2, varscan2
- THSD4 | c.2682A>T p.E894D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.551); catalogued as COSV55965431; called by muse, mutect2, varscan2
- ATP7A | c.1482C>T p.V494= | Silent (SNP) | VAF 17/467 reads (4%) | catalogued as COSV100431899; called by muse, mutect2
- NUP98 | c.3039C>T p.F1013= (on ENST00000359171 / NM_001365126.1; = p.F996= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 9/178 reads (5%) | catalogued as COSV100263676; called by muse, mutect2
- PCDHA12 | c.2055C>T p.G685= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV56488036; called by muse, mutect2, varscan2
- TBC1D9 | c.2139G>A p.V713= | Silent (SNP) | VAF 34/625 reads (5%) | catalogued as COSV101464416; called by muse, mutect2
